Surgical pathology report (de-identified scan), TCGA case TCGA-SG-A6Z4, project TCGA-SARC (Sarcoma), tissue source site Cleveland Clinic Foundation, specimen TCGA-SG-A6Z4-01A (Primary Tumor).

[page 1 of 2]
Results

Patient Info

Patient Name

Sex

DOB

Results

Submitting Physician:

FINAL DIAGNOSIS

A. Left thigh sarcoma, excision:

- Undifferentiated pleomorphic sarcoma with myogenic differentiation (FNCLCC, Grade 3/3).
- See comment.

ICD-O-3
Sarcoma, pleomorphic cell
undifferentiated (8802/3)
(8805/3)
Code to highest 8805/3
Site: Thigh NOS C49.2
QD 8/11/13

COMMENT

SOFT TISSUE TUMOR

Specimen type: Wide excision

Site: Left thigh

Depth

deep

Specify depth (all that apply): Intramuscular

Size

Greatest dimension: 11 cm

Additional two dimensions: 6.0 x 5.0 cm

Histologic type: Undifferentiated pleomorphic sarcoma with myogenic differentiation

Mitotic rate (per 5 HPFs): 44

Necrosis:

present

Extent (%): 30

Pre-treatment: No

Margins

Uninvolved by sarcoma

Distance from closest margin: 4 mm (microscopic measurement)

Specify margin: Anterior soft tissue margin

Lymph nodes

Number examined: 0

Number positive: Not applicable

FNCLCC grade

grade: 3/3

AJCC pathologic stage (pTNM)

stage: pT2b

Immunohistochemical stains have been performed on the prior biopsy
(redacted) and are not repeated.

[page 2 of 2]
[REDACTED]

(Electronic Signature)

SPECIMEN SUBMITTED
A: LEFT THIGH SARCOMA

CLINICAL DATA
L THIGH MASS

INTRAOPERATIVE CONSULT DIAGNOSIS
A. Margins grossly negative for tumor (

GROSS DESCRIPTION

A. Received in formalin is an unoriented segment of bone with attached soft tissue measuring 22 x 12 x 9.5 cm. The bone measures 22 cm in length x 3.2 cm in greatest diameter. The bone has been previously cut with a bone saw longitudinally. Situated within the soft tissue on top of the bone is a mass measuring 11 x 6 x 5 cm. The mass has a yellow firm cut surface with areas of cystic and necrotic degeneration (approximately 30%). The soft tissue margin overlying the mass (anterior) is 0.6 cm from the tumor, and is inked in black. The mass is situated 4.5 cm from the proximal line of resection and 6.5 cm from the distal line of resection. The mass is greater than 1.8cm from the lateral margins. The mass closely approximates but does not appear to involve the underlying bone. Representative sections are submitted as follows: A1-A3 mass with nearest soft tissue line of resection, A4-A7 representative sections of tumor, A8 tumor with nearest underlying bone following decalcification, A9-A10 proximal line of resection following decalcification, A11-A12 distal line of resection following decalcification.

[REDACTED]

Submitted by:
Location:
Test performed by:

Lab and Collection

Result History

Result Information

Result Date and Time

Status
Final result

Provider Status
Ordered

Status:

This result is currently not released to

Display Full Result Report

Display Order Report

Criteria	W 7/24/13	Yes	No

Source: NCI Genomic Data Commons file 44f5c2e9-25be-4b95-a48a-8a740fb91da6 (TCGA-SG-A6Z4.26732F7C-19B5-4F8E-8986-E3BDABBBD6A2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).